Somatic mutation profile of tumor specimen MP2PRT-PAPFHT-TMP1-A (aliquot MP2PRT-PAPFHT-TMP1-A-1-0-D-A83A-36) from MP2PRT case MP2PRT-PAPFHT, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 12.8 years (4,684 days).
Specimen MP2PRT-PAPFHT-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0eba8d4c-56c4-447d-b7a3-916e69fcfe86.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAPFHT-NM1-A (Blood Derived Cancer - Bone Marrow, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAPFHT-NM1-A-1-0-D-A83A-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/49023961-f4ce-40a0-b55e-d72710f241a5

The open-access MAF lists 13 somatic variants for this specimen: 6 protein-altering or splice-affecting, 6 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Silent 6, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.35G>C p.G12A | Missense Mutation (SNP) | VAF 93/271 reads (34%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.525); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AGBL1 | c.673C>T p.R225W | Missense Mutation (SNP) | VAF 29/472 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.033); catalogued as rs374832275; called by muse, mutect2
- ALG10 | c.832G>A p.D278N | Missense Mutation (SNP) | VAF 27/349 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748976308; called by muse, mutect2
- CYB5R3 | c.140T>C p.L47P | Missense Mutation (SNP) | VAF 106/285 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751975938; called by muse, mutect2
- SYT6 | c.464G>A p.R155H (on ENST00000610222 / NM_001366225.1; = p.R70H on NM_205848.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 50/397 reads (13%) | SIFT tolerated (0.48); PolyPhen benign (0.01); catalogued as rs138691067; called by muse, mutect2, varscan2
- TMPRSS9 | c.2050G>A p.V684M (on ENST00000648592; = p.V650M on NM_182973.2) | Missense Mutation (SNP) | VAF 108/287 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs774953473, COSV60227513; called by muse, mutect2, varscan2
- APOL5 | c.1098T>A p.V366= | Silent (SNP) | VAF 162/397 reads (41%) | called by muse, mutect2, varscan2
- KPTN | c.1095C>G p.P365= | Silent (SNP) | VAF 196/506 reads (39%) | catalogued as rs1276244158; called by muse, mutect2, varscan2
- OBSCN | c.12363G>C p.G4121= | Silent (SNP) | VAF 190/498 reads (38%) | catalogued as COSV99482372; called by muse, mutect2, varscan2
- PTPN5 | c.345C>T p.N115= | Silent (SNP) | VAF 33/400 reads (8%) | catalogued as rs552726407, COSV62125242, COSV62128243; called by muse, mutect2
- TOPAZ1 | c.2892C>T p.T964= | Silent (SNP) | VAF 123/341 reads (36%) | called by muse, mutect2, varscan2
- VSIG2 | c.69C>T p.A23= | Silent (SNP) | VAF 109/271 reads (40%) | catalogued as rs756090840; called by muse, mutect2, varscan2
- NEB | c.8889+529C>T | Intron (SNP) | VAF 21/326 reads (6%) | called by muse, mutect2
